Somatic mutation profile of tumor specimen ALCH-B2RN-TTP1-A (aliquot ALCH-B2RN-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2RN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.9 years (20,060 days).
Specimen ALCH-B2RN-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3418dff7-b1fb-4a00-83c5-8ed9bf98c7d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2RN-NB1-A (Blood Derived Normal), aliquot ALCH-B2RN-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c12ed40-b8c1-4229-9ccf-1ef0915b6982

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Splice Region 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028+2T>C p.X1010_splice | Splice Site (SNP) | VAF 25/200 reads (13%) | hotspot (GDC flag); catalogued as COSV100577355, COSV59257966, COSV59268376, COSV59269013; called by muse, mutect2, varscan2
- PLEC | c.4373C>T p.T1458M (on ENST00000322810 / NM_201380.4; = p.T1348M on NM_000445.5) | Missense Mutation (SNP) | VAF 34/449 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs782146862, COSV59654257; ClinVar: uncertain significance; called by muse, mutect2
- CPSF4 | c.767A>C p.N256T | Missense Mutation (SNP) | VAF 17/404 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- LTBP4 | c.2403C>A p.H801Q (on ENST00000308370 / NM_001042544.1; = p.H764Q on NM_003573.2) | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.306); called by muse, mutect2
- MGLL | c.234T>C p.V78= (on ENST00000398104 / NM_001003794.2; = p.V88= on NM_007283.6) | Splice Region (SNP) | VAF 13/282 reads (5%) | called by muse, mutect2
- NCKAP1L | c.1966C>G p.P656A | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2
- SLC38A4 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 36/421 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- B3GLCT | c.-83C>A | 5'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- SLC4A10 | c.1442+15C>T | Intron (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
